Gene-level copy-number profile of tumor specimen 1105261 from CPTAC case C243048, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen 1105261: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 00a1663a-5887-43da-96d1-6fccddb593cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105206 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/a5c415d6-fac9-474a-a5d3-ba5675dccec0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 12,772; copy number 2: 41,829; copy number 3: 2,595; copy number 4: 683; copy number 5: 491.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:18,236,123–21,779,522, 25 genes (within-gene range 0–1): SNORD81, RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1.
- chr5:21,882,585–21,884,310, 1 gene (within-gene range 0–1): HSPD1P1.
- chr9:138,199,933–138,253,217, 2 genes: AL954642.1, FAM157B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 491 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:10,717,773–13,609,168, 49 genes, copy number 5: AC092687.2, ATP6V1C2, RNU7-138P, AC092687.3, PDIA6, RNU7-176P, LINC01954, AC092687.1, AC079587.1, KCNF1, RPL6P4, AC062028.1, C2orf50, SLC66A3, ROCK2, RNU6-1081P, AIDAP1, PPIAP60, AC099344.1, LINC00570, AC099344.2, E2F6, GREB1, RNA5SP84, MIR4429, RNU2-13P, 5S_rRNA, RN7SL674P, NTSR2, CDK8P1, AC106875.2, LPIN1, AC106875.1, AC012456.1, AC012456.2, MIR548S, MIR3681HG, MIR4262, SNORD18, MIR3681, RNU6-843P, AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1, AC073062.1.
- chr9:101,569,352–105,776,629, 48 genes, copy number 5 (within-gene range 2–5): GRIN3A, PPP3R2, MTND3P4, ARL2BPP7, RNU6-329P, AL442644.1, LINC00587, ZYG11AP1, AL365396.1, CYLC2, AL589823.1, LINC01492, AL390962.1, RNA5SP291, SMC2-AS1, SMC2, TOPORSLP, AL512646.1, OR13F1, AL450426.1, OR13C4, OR13C3, OR13C8, OR13D2P, OR13C5, OR13C2, OR13C9, OR13I1P, OR13C1P, OR13D1, OR13D3P, NIPSNAP3A, NIPSNAP3B, ABCA1, AL359182.1, CT70, AL591506.1, RN7SKP191, SLC44A1, FSD1L, RALGAPA1P1, AL158070.1, FKTN, AL158070.2, TAL2, TMEM38B, AL592437.1, DEPDC1P2.
- chr9:119,935,053–128,163,924, 187 genes, copy number 5 (broad region; genes not listed).
- chr9:128,729,786–133,228,591, 118 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr9:134,849,298–136,245,812, 42 genes, copy number 5: MIR3689C, MIR3689A, MIR3689D1, MIR3689B, MIR3689D2, MIR3689E, MIR3689F, AL603650.1, FCN2, FCN1, AL353611.1, AL353611.2, OLFM1, AL390778.1, AL390778.2, C9orf62, AL353615.1, SOCS5P2, PPP1R26-AS1, PPP1R26, C9orf116, MRPS2, AL161452.1, LCN1, OBP2A, PAEP, LINC01502, PAEPP1, AL354761.1, GLT6D1, LCN9, SOHLH1, KCNT1, CAMSAP1, AL355574.1, UBAC1, NACC2, LINC02846, TMEM250, AL138781.1, LHX3, QSOX2.
- chr9:136,249,978–136,251,205, 1 gene, copy number 5: CR392000.1.
- chr19:567,210–1,228,431, 46 genes, copy number 5 (within-gene range 1–5): AC009005.1, BSG, HCN2, AC005559.1, POLRMT, AC004449.1, FGF22, RNF126, AC004156.1, FSTL3, PRSS57, RPS2P52, PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1.

Autosomal genes at a single copy (total copy number 1): 11,089. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
